Somatic mutation profile of tumor specimen C3N-02283-02 (aliquot CPT0126530006) from CPTAC case C3N-02283, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 67.3 years (24,583 days).
Specimen C3N-02283-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 306bad9d-9719-4f2e-a7d2-b4d632c9cc1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02283-31 (Blood Derived Normal), aliquot CPT0126580002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01caf826-605b-4cf8-80b6-d254eea0fd03

The open-access MAF lists 869 somatic variants for this specimen: 586 protein-altering or splice-affecting, 166 silent, 117 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 502, Silent 166, Intron 61, Nonsense Mutation 45, 5'UTR 16, 3'UTR 14, Splice Site 13, RNA 13, Splice Region 12, 5'Flank 10, Frame Shift Del 10, 3'Flank 3.

Variants (750 of 869; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CC2D2A | c.2671G>A p.E891K | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs863225178; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RIT1 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs777520196, COSV64170902, COSV64171029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.673-1G>T p.X225_splice | Splice Site (SNP) | VAF 334/368 reads (91%) | hotspot (GDC flag); catalogued as rs878854073, CS011061, COSV52662773, COSV52705331, COSV52707963, COSV53154363; ClinVar: pathogenic; called by mutect2, varscan2
- ABCB5 | c.2962C>A p.L988M (on ENST00000404938 / NM_001163941.2; = p.L543M on NM_178559.6) | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as COSV99329326; called by muse, varscan2
- ABCD2 | c.1421T>A p.V474E | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.025); catalogued as COSV104394065; called by muse, mutect2, varscan2
- ACACB | c.4690G>T p.E1564* | Nonsense Mutation (SNP) | VAF 71/237 reads (30%) | catalogued as COSV58130639; called by muse, mutect2, varscan2
- ACHE | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 60/154 reads (39%) | catalogued as COSV99573661; called by muse, mutect2, varscan2
- ACSM2B | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as rs771713657, COSV61657732; called by muse, mutect2, varscan2
- ADAMTS20 | c.2909G>T p.W970L | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101166131; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2279C>T p.S760L | Missense Mutation (SNP) | VAF 187/1006 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.535); catalogued as rs146017344; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADCY2 | c.2094G>C p.M698I | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs753702634; called by muse, mutect2, varscan2
- ADGRF2 | c.918C>G p.F306L (on ENST00000296862 / NM_001368115.2; = p.F238L on NM_153839.7) | Missense Mutation (SNP) | VAF 64/131 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV99731294; called by muse, mutect2, varscan2
- AEBP1 | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1307490420, COSV56257895; called by muse, mutect2, varscan2
- AHNAK | c.17144C>T p.P5715L | Missense Mutation (SNP) | VAF 101/167 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1489145306; called by muse, mutect2, varscan2
- AHNAK | c.13219C>G p.L4407V | Missense Mutation (SNP) | VAF 138/225 reads (61%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.99); catalogued as COSV57212742; called by muse, mutect2, varscan2
- ALPK2 | c.5599G>C p.V1867L | Missense Mutation (SNP) | VAF 77/88 reads (88%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as rs201637680; called by muse, mutect2, varscan2
- ARAP2 | c.2141A>G p.N714S | Missense Mutation (SNP) | VAF 168/296 reads (57%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.67); catalogued as rs202144416; called by muse, mutect2, varscan2
- ARHGAP12 | c.2347C>G p.L783V | Missense Mutation (SNP) | VAF 112/223 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1474354871, COSV60962940; called by muse, mutect2, varscan2
- ARHGAP22 | c.363G>T p.E121D | Missense Mutation (SNP) | VAF 194/206 reads (94%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV50934576; called by muse, mutect2, varscan2
- ARHGAP5 | c.490G>C p.D164H | Missense Mutation (SNP) | VAF 77/134 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61538133; called by muse, mutect2, varscan2
- ARHGEF25 | c.1516C>A p.Q506K | Missense Mutation (SNP) | VAF 78/388 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99677993; called by muse, mutect2, varscan2
- BAZ2B | c.6001G>A p.E2001K | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.63); catalogued as COSV58595072; called by muse, mutect2, varscan2
- BRINP2 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 73/117 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs774540232; called by muse, mutect2, varscan2
- BRINP3 | c.256G>T p.V86L | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as rs778175581; called by muse, mutect2, varscan2
- BTN3A3 | c.142G>C p.A48P | Missense Mutation (SNP) | VAF 167/401 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.445); catalogued as COSV55073113; called by muse, mutect2, varscan2
- C8A | c.677C>A p.S226Y | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV63485181; called by muse, mutect2, varscan2
- CARD11 | c.2125G>T p.G709C | Missense Mutation (SNP) | VAF 76/210 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100829234; called by muse, mutect2, varscan2
- CCDC121 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 297/332 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53115337; called by muse, mutect2, varscan2
- CCDC168 | c.12934G>T p.G4312W | Missense Mutation (SNP) | VAF 53/62 reads (85%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.61); catalogued as COSV59419498; called by muse, mutect2, varscan2
- CCDC38 | c.878C>A p.P293Q | Missense Mutation (SNP) | VAF 69/282 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV60182666; called by muse, mutect2, varscan2
- CCT8 | c.1394C>G p.S465C | Missense Mutation (SNP) | VAF 179/192 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54506247; called by muse, mutect2, varscan2
- CDH20 | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 80/95 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53005591; called by muse, mutect2, varscan2
- CDH23 | c.2500C>T p.R834C | Missense Mutation (SNP) | VAF 132/385 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs372387390; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH8 | c.2311C>A p.Q771K | Missense Mutation (SNP) | VAF 78/297 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100181544; called by muse, varscan2
- CDPF1 | c.240C>G p.F80L | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs747597227; called by muse, mutect2, varscan2
- CFAP65 | c.3490C>A p.P1164T | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.08); catalogued as rs375107182; called by mutect2, varscan2
- CLK3 | c.166G>C p.D56H | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV61415020; called by muse, mutect2, varscan2
- CNKSR2 | c.1709G>A p.R570H | Missense Mutation (SNP) | VAF 97/103 reads (94%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1321222847; called by muse, mutect2, varscan2
- CTNND2 | c.1372+3G>T | Splice Region (SNP) | VAF 83/179 reads (46%) | catalogued as rs776624229; called by muse, mutect2, varscan2
- DBX2 | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.399); catalogued as COSV60339669; called by muse, mutect2
- DCN | c.45G>T p.W15C | Missense Mutation (SNP) | VAF 104/316 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.662); catalogued as rs912177379; called by muse, mutect2, varscan2
- DDR1 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 227/514 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1225801001; called by muse, mutect2, varscan2
- DEFB118 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 492/789 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.312); catalogued as COSV53621389; called by muse, mutect2, varscan2
- DIDO1 | c.3655C>G p.Q1219E | Missense Mutation (SNP) | VAF 75/528 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as COSV99824345; called by muse, mutect2, varscan2
- DLL3 | c.1346C>A p.S449Y | Missense Mutation (SNP) | VAF 602/838 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV52693525; called by muse, mutect2, varscan2
- DMXL2 | c.1768C>T p.H590Y | Missense Mutation (SNP) | VAF 196/223 reads (88%) | SIFT tolerated (0.36); PolyPhen benign (0.04); catalogued as COSV51855406; called by muse, mutect2, varscan2
- DNAH10 | c.6948G>T p.L2316F (on ENST00000409039; = p.L2255F on NM_207437.3) | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101292333; called by muse, mutect2, varscan2
- DNAI4 | c.1937G>T p.G646V | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.108); catalogued as rs762079969; called by muse, mutect2, varscan2
- DONSON | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as rs964516394; called by muse, mutect2, varscan2
- DPP6 | c.1695C>A p.H565Q (on ENST00000377770 / NM_001364500.2; = p.H503Q on NM_001936.5) | Missense Mutation (SNP) | VAF 56/199 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as rs1390494680; called by muse, mutect2, varscan2
- DSG4 | c.231C>A p.C77* | Nonsense Mutation (SNP) | VAF 532/598 reads (89%) | catalogued as rs200935383; called by muse, mutect2, varscan2
- EHD2 | c.1201G>T p.E401* | Nonsense Mutation (SNP) | VAF 63/257 reads (25%) | catalogued as COSV54406726; called by muse, mutect2, varscan2
- ERICH3 | c.4366G>A p.E1456K | Missense Mutation (SNP) | VAF 111/176 reads (63%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV58613050; called by muse, mutect2, varscan2
- ERVFRD-1 | c.1427C>A p.T476N | Missense Mutation (SNP) | VAF 74/166 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.878); catalogued as COSV65370147; called by muse, mutect2, varscan2
- ERVV-1 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 142/801 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.483); catalogued as rs1235069793; called by muse, mutect2, varscan2
- EVC2 | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 64/153 reads (42%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.001); catalogued as COSV53829504; called by muse, mutect2, varscan2
- F8 | c.4507G>C p.D1503H | Missense Mutation (SNP) | VAF 167/183 reads (91%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs782504502; called by muse, mutect2, varscan2
- FAM135B | c.2811G>T p.L937F | Missense Mutation (SNP) | VAF 76/380 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99420764; called by muse, mutect2, varscan2
- FCRL1 | c.934G>T p.G312W | Missense Mutation (SNP) | VAF 63/252 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV63824958; called by muse, mutect2, varscan2
- FGF3 | c.337G>T p.A113S | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.145); catalogued as COSV61925510; called by muse, mutect2, varscan2
- FRMPD1 | c.4200G>T p.W1400C | Missense Mutation (SNP) | VAF 154/170 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100899535; called by muse, mutect2, varscan2
- GABRA5 | c.1183G>T p.A395S | Missense Mutation (SNP) | VAF 99/264 reads (38%) | SIFT tolerated (0.89); PolyPhen benign (0.006); catalogued as COSV59477674; called by muse, mutect2, varscan2
- GABRB1 | c.1234G>T p.E412* | Nonsense Mutation (SNP) | VAF 226/381 reads (59%) | catalogued as COSV54981483, COSV99782313; called by muse, mutect2, varscan2
- GBA3 | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 88/190 reads (46%) | catalogued as rs576810567; called by muse, mutect2, varscan2
- GCH1 | c.428A>G p.H143R | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs764265181; called by muse, mutect2, varscan2
- GEN1 | c.2163G>T p.K721N | Missense Mutation (SNP) | VAF 89/102 reads (87%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99060067; called by muse, mutect2, varscan2
- GJB2 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 68/151 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as rs777588424; called by muse, mutect2, varscan2
- GNPNAT1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 42/76 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV53592475; called by muse, varscan2
- GPX1 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 40/214 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as COSV69041927; called by muse, varscan2
- GPX6 | c.516G>T p.E172D | Missense Mutation (SNP) | VAF 220/614 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV62657631; called by muse, mutect2, varscan2
- GRM1 | c.3300C>A p.S1100R | Missense Mutation (SNP) | VAF 361/778 reads (46%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.346); catalogued as rs1227591846, COSV51316728; called by muse, mutect2, varscan2
- GRM6 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 205/226 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs767670928; called by muse, mutect2, varscan2
- H4C3 | c.71G>C p.R24P | Missense Mutation (SNP) | VAF 115/275 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1285215160; called by muse, mutect2, varscan2
- HCN4 | c.702C>A p.F234L | Missense Mutation (SNP) | VAF 310/343 reads (90%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as COSV56083418; called by muse, mutect2, varscan2
- HEATR1 | c.3247G>C p.D1083H | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as rs1195526194; called by muse, mutect2, varscan2
- HEG1 | c.2995G>A p.E999K | Missense Mutation (SNP) | VAF 119/318 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs746472724; called by muse, mutect2, varscan2
- HEPACAM | c.872C>G p.P291R | Missense Mutation (SNP) | VAF 393/423 reads (93%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV53430045; called by muse, mutect2, varscan2
- INTS11 | c.1294+1G>A p.X432_splice | Splice Site (SNP) | VAF 63/98 reads (64%) | catalogued as rs373419344; called by muse, mutect2, varscan2
- IRF3 | c.338-6C>T | Splice Region (SNP) | VAF 77/244 reads (32%) | catalogued as rs781489544; called by muse, mutect2, varscan2
- ITGA2 | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 95/228 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56863432; called by muse, mutect2, varscan2
- JADE1 | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 181/200 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1363055119; called by muse, mutect2, varscan2
- KCNF1 | c.472G>T p.E158* | Nonsense Mutation (SNP) | VAF 345/380 reads (91%) | catalogued as COSV54462309, COSV54464047; called by muse, mutect2, varscan2
- KHDC1L | c.262G>T p.V88L | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT tolerated (0.89); PolyPhen benign (0.141); catalogued as COSV64893265; called by muse, mutect2, varscan2
- KIAA0408 | c.1862G>T p.W621L | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs745704294, COSV64105097; called by muse, varscan2
- KIF21B | c.4268C>T p.S1423L (on ENST00000422435 / NM_001252100.2; = p.S1410L on NM_017596.4) | Missense Mutation (SNP) | VAF 153/259 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs1191391325, COSV59754665; called by muse, mutect2, varscan2
- KIF2C | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 60/287 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV64764060, COSV64764146; called by muse, mutect2, varscan2
- KIRREL2 | c.1246C>A p.R416S | Missense Mutation (SNP) | VAF 79/270 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99384191; called by muse, mutect2, varscan2
- KMT2B | c.4462C>T p.R1488W | Missense Mutation (SNP) | VAF 40/57 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs773513850, COSV55859648; ClinVar: likely benign; called by muse, mutect2, varscan2
- KMT2E | c.4672C>T p.Q1558* | Nonsense Mutation (SNP) | VAF 159/350 reads (45%) | catalogued as COSV57573067; called by muse, mutect2, varscan2
- KRT1 | c.1796C>G p.S599C | Missense Mutation (SNP) | VAF 124/439 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.712); catalogued as COSV99358516; called by muse, mutect2, varscan2
- KRTAP10-8 | c.403G>T p.V135L | Missense Mutation (SNP) | VAF 529/590 reads (90%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100554858; called by muse, mutect2, varscan2
- LAMC2 | c.1912C>T p.Q638* | Nonsense Mutation (SNP) | VAF 112/194 reads (58%) | catalogued as rs1343526840; called by muse, mutect2, varscan2
- LCE2B | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 202/2091 reads (10%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.322); catalogued as COSV64227751; called by muse, mutect2
- LRIT1 | c.1286G>T p.R429L | Missense Mutation (SNP) | VAF 297/327 reads (91%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV100928154; called by muse, mutect2, varscan2
- LRP1B | c.13223C>A p.P4408H | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV67254284; called by muse, mutect2, varscan2
- LRRC9 | c.1198C>G p.R400G | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV99580070; called by muse, mutect2, varscan2
- LRSAM1 | c.2020G>C p.E674Q | Missense Mutation (SNP) | VAF 152/172 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773487480, COSV55940380; called by muse, mutect2, varscan2
- LTBP2 | c.4202C>T p.T1401M | Missense Mutation (SNP) | VAF 125/436 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs760340005; called by muse, mutect2, varscan2
- MAGEC1 | c.633G>C p.L211F | Missense Mutation (SNP) | VAF 175/562 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.587); catalogued as COSV53573716; called by muse, varscan2
- MAP1LC3B | c.39C>T p.F13= | Splice Region (SNP) | VAF 32/109 reads (29%) | catalogued as rs947434234; called by muse, varscan2
- MAP3K7CL | c.371-1G>C p.X124_splice | Splice Site (SNP) | VAF 50/152 reads (33%) | catalogued as COSV54508411; called by muse, mutect2, varscan2
- MEFV | c.1182C>G p.I394M | Missense Mutation (SNP) | VAF 61/207 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54825105; called by muse, mutect2, varscan2
- METTL21C | c.154C>G p.L52V | Missense Mutation (SNP) | VAF 44/54 reads (81%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.664); catalogued as COSV99940018; called by muse, mutect2, varscan2
- MFSD12 | c.436C>G p.Q146E | Missense Mutation (SNP) | VAF 212/252 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs777779411; called by muse, mutect2, varscan2
- MIA2 | c.1699G>C p.D567H | Missense Mutation (SNP) | VAF 62/263 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as COSV54484114; called by muse, mutect2, varscan2
- MMP8 | c.902G>T p.R301M | Missense Mutation (SNP) | VAF 68/70 reads (97%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV52633797; called by muse, mutect2, varscan2
- MMP9 | c.2019C>G p.F673L | Missense Mutation (SNP) | VAF 194/732 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100812429; called by muse, mutect2, varscan2
- MOK | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV51966116; called by muse, mutect2, varscan2
- MRC1 | c.2702C>T p.T901I | Missense Mutation (SNP) | VAF 182/1897 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.055); catalogued as rs1319314200; called by muse, mutect2
- MROH2B | c.932C>A p.P311H | Missense Mutation (SNP) | VAF 100/229 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV68182649; called by mutect2, varscan2
- MTUS2 | c.1360G>C p.E454Q | Missense Mutation (SNP) | VAF 98/232 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV70922091; called by muse, mutect2, varscan2
- MUC3A | c.8741del p.P2914Hfs*32 | Frame Shift Del (DEL) | VAF 36/280 reads (13%) | catalogued as COSV100114939; called by mutect2, pindel
- MYH6 | c.4648G>C p.E1550Q | Missense Mutation (SNP) | VAF 221/392 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV100676308; called by muse, mutect2, varscan2
- MYH8 | c.2413C>G p.Q805E | Missense Mutation (SNP) | VAF 87/153 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV67965584; called by muse, mutect2, varscan2
- MYOM1 | c.1365G>T p.W455C | Missense Mutation (SNP) | VAF 317/561 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374593777; called by muse, mutect2, varscan2
- NBEAL1 | c.4415C>T p.S1472L | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as rs754532042, COSV71373679; called by muse, mutect2, varscan2
- NEB | c.9986A>G p.Y3329C | Missense Mutation (SNP) | VAF 89/239 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV99425404; called by muse, mutect2, varscan2
- NECAP2 | c.23C>G p.S8W | Missense Mutation (SNP) | VAF 119/227 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59188115, COSV59188823; called by muse, mutect2, varscan2
- NFKBIE | c.445G>A p.E149K (on ENST00000275015; = p.E10K on NM_004556.3) | Missense Mutation (SNP) | VAF 642/1435 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.124); catalogued as rs1322332758; called by muse, mutect2, varscan2
- NFKBIZ | c.1394G>A p.R465K | Missense Mutation (SNP) | VAF 80/189 reads (42%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.625); catalogued as rs1026213658; called by muse, mutect2, varscan2
- NLRC5 | c.4071-6C>T | Splice Region (SNP) | VAF 28/114 reads (25%) | catalogued as rs768150451; called by muse, mutect2, varscan2
- OR10Q1 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 73/264 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as rs772343084, COSV57472272; called by muse, mutect2, varscan2
- OR2J2 | c.263G>A p.G88D | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.207); catalogued as rs986904037, COSV101013413; called by muse, mutect2, varscan2
- OR56A5 | c.721C>G p.L241V | Missense Mutation (SNP) | VAF 199/226 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1309902544; called by muse, mutect2, varscan2
- OR5B21 | c.744C>G p.F248L | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV64481683; called by muse, mutect2, varscan2
- OR5H1 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 115/267 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV63402059, COSV63403022; called by muse, mutect2, varscan2
- OR5I1 | c.293G>C p.G98A | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.262); catalogued as COSV56886384, COSV56887803; called by muse, mutect2, varscan2
- OR8D2 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62488664; called by muse, mutect2, varscan2
- OR8G5 | c.690C>G p.Y230* | Nonsense Mutation (SNP) | VAF 208/232 reads (90%) | catalogued as COSV100422279; called by muse, varscan2
- OTOGL | c.5564C>T p.S1855L (on ENST00000547103; = p.S1846L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/78 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as COSV54020093; called by muse, mutect2, varscan2
- PANX3 | c.966del p.I323Sfs*6 | Frame Shift Del (DEL) | VAF 161/245 reads (66%) | catalogued as COSV52511089; called by mutect2, pindel, varscan2
- PCDH10 | c.824C>A p.T275N | Missense Mutation (SNP) | VAF 189/225 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV52105239; called by muse, mutect2, varscan2
- PCDH17 | c.1343G>T p.G448V | Missense Mutation (SNP) | VAF 101/131 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1160706757, COSV64973113; called by muse, mutect2, varscan2
- PCDHA12 | c.2036C>A p.S679* | Nonsense Mutation (SNP) | VAF 146/358 reads (41%) | catalogued as COSV56552943; called by muse, varscan2
- PDE1B | c.234C>G p.I78M | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs1347181278; called by muse, mutect2, varscan2
- PHLDA1 | c.974C>G p.P325R | Missense Mutation (SNP) | VAF 55/97 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV56998253; called by muse, mutect2, varscan2
- PIK3C2G | c.3053C>A p.A1018E (on ENST00000676171; = p.A977E on NM_004570.5) | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV56826171; called by muse, mutect2, varscan2
- PLCB2 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 83/97 reads (86%) | SIFT tolerated (0.1); PolyPhen benign (0.165); catalogued as rs769726676; called by muse, mutect2, varscan2
- PLCE1 | c.4636C>G p.Q1546E | Missense Mutation (SNP) | VAF 208/226 reads (92%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.929); catalogued as rs751180713; called by muse, mutect2, varscan2
- PLEKHA5 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as rs1263682890; called by muse, mutect2, varscan2
- PLEKHA6 | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 145/231 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1171955931; called by muse, mutect2, varscan2
- PLEKHM2 | c.433G>T p.G145W | Missense Mutation (SNP) | VAF 160/291 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867582918, COSV104424786; called by muse, mutect2, varscan2
- PLXDC1 | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757389182, COSV59550898; called by muse, mutect2, varscan2
- PPP1R10 | c.1333G>C p.E445Q | Missense Mutation (SNP) | VAF 210/545 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as COSV64738912; called by muse, mutect2, varscan2
- PPP2R5E | c.115C>G p.Q39E | Missense Mutation (SNP) | VAF 65/193 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.155); catalogued as rs774544013; called by muse, mutect2, varscan2
- PRDM9 | c.783G>T p.W261C | Missense Mutation (SNP) | VAF 135/540 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57010102; called by muse, mutect2, varscan2
- PREP | c.929C>T p.P310L (on ENST00000369110; = p.P376L on NM_002726.5) | Missense Mutation (SNP) | VAF 194/458 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs372127457; called by muse, mutect2, varscan2
- PROM1 | c.561C>G p.I187M | Missense Mutation (SNP) | VAF 63/204 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.596); catalogued as COSV71699233; called by muse, mutect2, varscan2
- PRPF40A | c.2477G>A p.R826K | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV101344146; called by muse, mutect2, varscan2
- PRUNE2 | c.402C>G p.S134R | Missense Mutation (SNP) | VAF 84/108 reads (78%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs553816550, COSV65028213; called by muse, mutect2, varscan2
- PTPRK | c.1579A>T p.S527C | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV63893192; called by muse, mutect2, varscan2
- RACK1 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 119/137 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV65174436; called by muse, mutect2, varscan2
- RAMP3 | c.132C>A p.F44L | Missense Mutation (SNP) | VAF 70/215 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV54244949; called by muse, mutect2, varscan2
- RASA2 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs200745202; called by muse, mutect2, varscan2
- RASD2 | c.46G>C p.A16P | Missense Mutation (SNP) | VAF 150/167 reads (90%) | SIFT tolerated (0.29); PolyPhen benign (0.038); catalogued as COSV53352088; called by muse, mutect2, varscan2
- RESF1 | c.4703G>T p.S1568I | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.164); catalogued as rs746786063; called by muse, mutect2, varscan2
- RGPD3 | c.3271G>C p.E1091Q | Missense Mutation (SNP) | VAF 171/420 reads (41%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.45); catalogued as COSV58747713; called by muse, mutect2, varscan2
- RGS12 | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 90/474 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs371019581; called by muse, mutect2, varscan2
- RGS7 | c.1028G>T p.G343V | Missense Mutation (SNP) | VAF 120/243 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58542282; called by muse, mutect2
- RHBG | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 64/209 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV54806090; called by muse, mutect2, varscan2
- RHNO1 | c.239G>A p.R80K | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.147); catalogued as COSV100817050, COSV63485454; called by muse, mutect2, varscan2
- RNF10 | c.1940C>G p.S647C | Missense Mutation (SNP) | VAF 126/411 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs113560686; called by muse, mutect2, varscan2
- RNF149 | c.1082C>G p.S361* | Nonsense Mutation (SNP) | VAF 123/418 reads (29%) | catalogued as COSV54863406; called by muse, mutect2, varscan2
- RNF213 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 266/450 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.4); catalogued as rs142962817; called by muse, mutect2, varscan2
- ROBO4 | c.2271C>A p.C757* | Nonsense Mutation (SNP) | VAF 56/64 reads (88%) | catalogued as rs1167035631; called by muse, mutect2, varscan2
- RPGRIP1L | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs775563304; called by muse, mutect2, varscan2
- RPLP0 | c.439A>G p.I147V | Missense Mutation (SNP) | VAF 140/271 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV56114516; called by muse, mutect2, varscan2
- RTF1 | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 62/74 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs532994281, COSV67477871; called by muse, mutect2, varscan2
- SALL3 | c.1831G>C p.A611P | Missense Mutation (SNP) | VAF 80/92 reads (87%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV73306040; called by muse, mutect2, varscan2
- SCRIB | c.3035G>T p.G1012V | Missense Mutation (SNP) | VAF 39/215 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554635768, COSV57593210; called by muse, mutect2, varscan2
- SIGLEC6 | c.179C>G p.S60W | Missense Mutation (SNP) | VAF 147/246 reads (60%) | SIFT tolerated (0.23); PolyPhen benign (0.183); catalogued as rs748993718, COSV58435362; called by muse, mutect2, varscan2
- SIK3 | c.1868G>A p.R623Q (on ENST00000445177 / NM_001366686.2; = p.R581Q on NM_001281749.3) | Missense Mutation (SNP) | VAF 141/151 reads (93%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as rs745814303, COSV99407827; called by muse, mutect2, varscan2
- SLC26A5 | c.460G>C p.D154H | Missense Mutation (SNP) | VAF 138/386 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1352988404, COSV59698624; called by muse, mutect2, varscan2
- SLC39A11 | c.109-1G>C p.X37_splice | Splice Site (SNP) | VAF 57/263 reads (22%) | catalogued as rs1442420132, COSV55300846; called by muse, mutect2, varscan2
- SLC39A12 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 316/399 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV101070094, COSV66201781; called by muse, mutect2, varscan2
- SNIP1 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.118); catalogued as COSV56167217; called by muse, mutect2, varscan2
- SNTG1 | c.966+1G>T p.X322_splice | Splice Site (SNP) | VAF 47/139 reads (34%) | catalogued as COSV52432623; called by muse, mutect2, varscan2
- SPATA16 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.747); catalogued as rs199868908; called by muse, mutect2, varscan2
- SPHKAP | c.2458G>A p.V820M | Missense Mutation (SNP) | VAF 46/80 reads (58%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs773664176; called by muse, mutect2, varscan2
- STAG1 | c.871A>G p.I291V | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs749700430; called by muse, mutect2, varscan2
- STEAP2 | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs144320893; called by muse, mutect2, varscan2
- TBC1D9B | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 131/144 reads (91%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as COSV62284478; called by muse, mutect2, varscan2
- TIMP3 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 306/336 reads (91%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs1436459662, COSV99831188; called by muse, mutect2, varscan2
- TRAV7 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 85/308 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.061); catalogued as rs1208321368; called by muse, mutect2, varscan2
- TRDV2 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 77/272 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as rs374840657; called by muse, mutect2, varscan2
- TRIM55 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 88/506 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52549080; called by muse, mutect2, varscan2
- TRMT1 | c.665G>T p.R222M | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.612); catalogued as COSV99679164; called by muse, mutect2, varscan2
- TROAP | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 79/276 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.288); catalogued as rs762827543, COSV57743866; called by muse, mutect2, varscan2
- TTN | c.86008C>T p.L28670F (on ENST00000591111; = p.L21246F on NM_003319.4) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | PolyPhen probably damaging (0.999); catalogued as COSV100635641; called by muse, mutect2, varscan2
- TTN | c.77250G>A p.W25750* (on ENST00000591111; = p.W18326* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 49/183 reads (27%) | catalogued as COSV60273236; called by muse, mutect2, varscan2
- TTN | c.75257G>C p.R25086T (on ENST00000591111; = p.R17662T on NM_003319.4) | Missense Mutation (SNP) | VAF 28/144 reads (19%) | PolyPhen probably damaging (0.996); catalogued as COSV59878390; called by muse, mutect2, varscan2
- TTN | c.33307G>C p.E11103Q (on ENST00000591111; = p.E10176Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/46 reads (61%) | PolyPhen benign (0.042); catalogued as COSV100625338; called by muse, mutect2, varscan2
- TTN | c.31702A>T p.M10568L (on ENST00000591111; = p.M9641L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/127 reads (48%) | PolyPhen benign (0); catalogued as rs200732179; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- U2AF2 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1286879775; called by muse, mutect2, varscan2
- UBR4 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (1); PolyPhen probably damaging (0.981); catalogued as rs1228725668; called by muse, mutect2, varscan2
- UNC13B | c.1097C>T p.S366F | Missense Mutation (SNP) | VAF 153/176 reads (87%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs1375998424; called by muse, mutect2, varscan2
- USH2A | c.399G>C p.K133N | Missense Mutation (SNP) | VAF 195/313 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV56432995; called by muse, mutect2, varscan2
- USP19 | c.2626C>T p.Q876* | Nonsense Mutation (SNP) | VAF 12/13 reads (92%) | catalogued as COSV60046004; called by muse, mutect2, varscan2
- VPS8 | c.4210G>T p.A1404S (on ENST00000625842 / NM_001349294.1; = p.A1402S on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 122/281 reads (43%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs1297515734, COSV54982122; called by muse, mutect2, varscan2
- VWF | c.3788C>T p.S1263L | Missense Mutation (SNP) | VAF 269/756 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.155); catalogued as rs758991219, CM126313, COSV54631938; called by muse, mutect2, varscan2
- WDR7 | c.832G>T p.G278W | Missense Mutation (SNP) | VAF 96/106 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99590073; called by muse, varscan2
- WIPF2 | c.1091C>G p.S364* | Nonsense Mutation (SNP) | VAF 32/56 reads (57%) | catalogued as COSV60275006; called by muse, mutect2, varscan2
- XCR1 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 292/318 reads (92%) | SIFT tolerated (0.16); PolyPhen benign (0.067); catalogued as rs758007235; called by muse, mutect2, varscan2
- XPO5 | c.1556G>T p.R519L | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.629); catalogued as COSV54832742; called by muse, mutect2, varscan2
- ZBTB14 | c.383G>C p.R128P | Missense Mutation (SNP) | VAF 69/113 reads (61%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV63697107; called by muse, mutect2, varscan2
- ZBTB2 | c.1324G>A p.V442M | Missense Mutation (SNP) | VAF 148/271 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.154); catalogued as rs376220688; called by muse, mutect2, varscan2
- ZEB1 | c.3136G>C p.E1046Q | Missense Mutation (SNP) | VAF 351/1112 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.203); catalogued as COSV58053339; called by muse, mutect2, varscan2
- ZFHX4 | c.5322G>T p.L1774F | Missense Mutation (SNP) | VAF 238/325 reads (73%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV99269900; called by muse, mutect2, varscan2
- ZFP69B | c.361G>T p.G121C | Missense Mutation (SNP) | VAF 145/306 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as COSV64316024; called by muse, mutect2, varscan2
- ZNF217 | c.1610G>T p.G537V | Missense Mutation (SNP) | VAF 150/316 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs748553841; called by muse, mutect2, varscan2
- ZNF318 | c.4780G>C p.G1594R | Missense Mutation (SNP) | VAF 180/400 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV58930674; called by muse, varscan2
- ZNF519 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 147/274 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.27); catalogued as rs1046145388; called by muse, mutect2, varscan2
- ZNF544 | c.1089C>G p.F363L | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as COSV54136803; called by muse, mutect2, varscan2
- ZNF599 | c.1475C>G p.S492C | Missense Mutation (SNP) | VAF 162/267 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61396219; called by muse, mutect2, varscan2
- ZNF77 | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 77/87 reads (89%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs200003978; called by muse, mutect2, varscan2
- ZZZ3 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 88/148 reads (59%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs749565657, COSV66231941; called by muse, varscan2
- ABCC11 | c.3295T>G p.L1099V | Missense Mutation (SNP) | VAF 148/266 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC053503.6 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ACP3 | c.79G>T p.D27Y | Missense Mutation (SNP) | VAF 52/413 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ACTR2 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- ADAM30 | c.1906G>C p.E636Q | Missense Mutation (SNP) | VAF 133/391 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ADGB | c.4374G>C p.E1458D | Missense Mutation (SNP) | VAF 181/460 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRE1 | c.848C>G p.S283C | Missense Mutation (SNP) | VAF 191/393 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRG4 | c.1705G>C p.E569Q | Missense Mutation (SNP) | VAF 72/78 reads (92%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRG4 | c.2359G>C p.D787H | Missense Mutation (SNP) | VAF 71/75 reads (95%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- ADGRL4 | c.2030G>T p.R677I | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AEBP1 | c.1834G>T p.E612* | Nonsense Mutation (SNP) | VAF 25/76 reads (33%) | called by muse, mutect2, varscan2
- AEBP1 | c.2728G>C p.G910R | Missense Mutation (SNP) | VAF 64/129 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGR3 | c.329C>G p.S110* | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- ALMS1 | c.9740C>A p.S3247* | Nonsense Mutation (SNP) | VAF 176/425 reads (41%) | called by muse, mutect2, varscan2
- AMDHD1 | c.980T>A p.V327E | Missense Mutation (SNP) | VAF 53/99 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANAPC1 | c.5185G>A p.E1729K | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.023); called by mutect2, varscan2
- ANKRD11 | c.4576G>T p.G1526C | Missense Mutation (SNP) | VAF 201/337 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- ANKRD26 | c.2856G>T p.K952N | Missense Mutation (SNP) | VAF 63/117 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- ANKRD30B | c.3931A>G p.R1311G | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ANKRD36C | c.2087C>A p.T696K | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ANKRD53 | c.1208C>G p.S403W | Missense Mutation (SNP) | VAF 98/205 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ANXA11 | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AP4B1 | c.2062G>A p.D688N | Missense Mutation (SNP) | VAF 154/355 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- APBB1IP | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ARHGAP39 | c.16G>C p.D6H | Missense Mutation (SNP) | VAF 203/303 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ARHGEF26 | c.2179G>T p.G727W | Missense Mutation (SNP) | VAF 91/154 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- ARMC3 | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 81/201 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ASH1L | c.4904C>G p.S1635C | Missense Mutation (SNP) | VAF 108/170 reads (64%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ASTN1 | c.2238A>T p.K746N | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- ATG2B | c.251del p.G84Afs*12 | Frame Shift Del (DEL) | VAF 16/79 reads (20%) | called by mutect2, pindel, varscan2
- ATP13A5 | c.3642C>G p.F1214L | Missense Mutation (SNP) | VAF 97/184 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- BBS9 | c.71G>T p.C24F | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- BDP1 | c.5018G>C p.S1673T | Missense Mutation (SNP) | VAF 72/84 reads (86%) | SIFT tolerated (0.07); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- BHMG1 | c.803G>T p.S268I | Missense Mutation (SNP) | VAF 80/230 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- BIRC6 | c.86T>C p.M29T | Missense Mutation (SNP) | VAF 275/305 reads (90%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- BIRC7 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 142/334 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- BPNT2 | c.572C>G p.T191S | Missense Mutation (SNP) | VAF 181/444 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BTBD7 | c.2878C>G p.L960V | Missense Mutation (SNP) | VAF 105/334 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C10orf71 | c.3488T>C p.L1163P | Missense Mutation (SNP) | VAF 255/282 reads (90%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by mutect2, varscan2
- C1QL3 | c.743C>G p.S248C | Missense Mutation (SNP) | VAF 92/693 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- C20orf96 | c.604G>A p.E202K (on ENST00000360321 / NM_153269.3; = p.E201K on NM_080571.1) | Missense Mutation (SNP) | VAF 121/199 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C2CD4D | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- C2CD5 | c.2570G>A p.G857E | Missense Mutation (SNP) | VAF 167/298 reads (56%) | SIFT tolerated (0.32); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- C5orf58 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CACHD1 | c.2784G>T p.R928S | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- CAD | c.2979G>C p.E993D | Missense Mutation (SNP) | VAF 163/200 reads (82%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CADM4 | c.1150G>C p.E384Q | Missense Mutation (SNP) | VAF 100/278 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- CAMSAP1 | c.3838G>A p.E1280K | Missense Mutation (SNP) | VAF 231/253 reads (91%) | SIFT deleterious (0); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- CARF | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 33/149 reads (22%) | called by muse, mutect2, varscan2
- CARMIL3 | c.3994C>G p.P1332A | Missense Mutation (SNP) | VAF 92/281 reads (33%) | SIFT tolerated, low confidence (0.89); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- CCDC105 | c.1180G>T p.D394Y | Missense Mutation (SNP) | VAF 180/203 reads (89%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CCDC113 | c.328del p.D110Tfs*2 | Frame Shift Del (DEL) | VAF 86/368 reads (23%) | called by mutect2, pindel, varscan2
- CCDC141 | c.3805C>A p.P1269T | Missense Mutation (SNP) | VAF 88/372 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- CCDC175 | c.369C>G p.D123E | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.21); called by muse, mutect2
- CCDC87 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2
- CD209 | c.462G>T p.K154N | Missense Mutation (SNP) | VAF 539/1104 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.771); called by muse, varscan2
- CD300LF | c.676T>A p.S226T | Missense Mutation (SNP) | VAF 64/243 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CDH23 | c.4186C>A p.P1396T | Missense Mutation (SNP) | VAF 220/251 reads (88%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- CEACAM20 | c.572del p.T191Kfs*55 | Frame Shift Del (DEL) | VAF 91/378 reads (24%) | called by mutect2, pindel, varscan2
- CFAP47 | c.7765G>T p.A2589S | Missense Mutation (SNP) | VAF 24/24 reads (100%) | SIFT tolerated (0.64); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- CFAP70 | c.3363C>G p.F1121L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- CHCHD5 | c.117G>A p.M39I | Missense Mutation (SNP) | VAF 69/161 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- CHD9 | c.2062G>C p.D688H | Missense Mutation (SNP) | VAF 54/94 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CHD9 | c.8230G>A p.G2744R (on ENST00000398510 / NM_001382353.1; = p.G2728R on NM_025134.7) | Missense Mutation (SNP) | VAF 59/235 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CHI3L2 | c.374T>A p.I125N | Missense Mutation (SNP) | VAF 74/162 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHML | c.1519C>G p.L507V | Missense Mutation (SNP) | VAF 104/164 reads (63%) | SIFT tolerated (0.15); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- CHRNA10 | c.774C>A p.F258L | Missense Mutation (SNP) | VAF 122/471 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CNGA3 | c.1388A>G p.K463R | Missense Mutation (SNP) | VAF 411/714 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- CNST | c.1501G>T p.A501S | Missense Mutation (SNP) | VAF 102/194 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- COL16A1 | c.2703G>T p.W901C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- COL4A5 | c.82-1G>T p.X28_splice | Splice Site (SNP) | VAF 135/153 reads (88%) | called by muse, mutect2, varscan2
- CSMD2 | c.712G>T p.D238Y | Missense Mutation (SNP) | VAF 115/432 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- CSMD3 | c.8774C>T p.P2925L (on ENST00000297405 / NM_001363185.1; = p.P2756L on NM_052900.3) | Missense Mutation (SNP) | VAF 224/296 reads (76%) | SIFT tolerated (1); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CTPS1 | c.65G>T p.S22I | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCAF12L1 | c.469C>A p.L157M | Missense Mutation (SNP) | VAF 211/233 reads (91%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DDX18 | c.1483G>C p.D495H | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- DEPDC5 | c.2557G>T p.E853* (on ENST00000400246; = p.E922* on NM_014662.5) | Nonsense Mutation (SNP) | VAF 34/36 reads (94%) | called by muse, mutect2, varscan2
- DGKI | c.797G>T p.C266F | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DIAPH2 | c.1828G>T p.G610* | Nonsense Mutation (SNP) | VAF 116/131 reads (89%) | called by muse, mutect2, varscan2
- DIAPH2 | c.1829G>T p.G610V | Missense Mutation (SNP) | VAF 115/130 reads (88%) | SIFT tolerated (0.14); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- DNAH14 | c.4111G>T p.G1371* (on ENST00000445597; = p.G1776* on NM_001367479.1) | Nonsense Mutation (SNP) | VAF 44/70 reads (63%) | called by muse, mutect2, varscan2
- DNAH14 | c.5278_5280del p.L1760del (on ENST00000445597; = p.L2165del on NM_001367479.1) | In Frame Del (DEL) | VAF 60/103 reads (58%) | called by mutect2, pindel, varscan2
- DNAJA2 | c.902G>T p.G301V | Missense Mutation (SNP) | VAF 52/82 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNM1 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 252/282 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPP4 | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 51/239 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- EEF2KMT | c.427C>G p.L143V | Missense Mutation (SNP) | VAF 152/534 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- EIF2S3B | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 343/667 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- EML5 | c.5132C>G p.S1711C (on ENST00000380664; = p.S1719C on NM_183387.3) | Missense Mutation (SNP) | VAF 182/282 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ENPP2 | c.657T>C p.T219= | Splice Region (SNP) | VAF 254/339 reads (75%) | called by muse, mutect2, varscan2
- ENTPD3 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 386/425 reads (91%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- ENTPD3 | c.1421A>T p.E474V | Missense Mutation (SNP) | VAF 388/432 reads (90%) | SIFT deleterious (0.03); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- EPRS1 | c.2648C>A p.S883* | Nonsense Mutation (SNP) | VAF 89/340 reads (26%) | called by muse, mutect2, varscan2
- EPS15 | c.887G>T p.G296V | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- F5 | c.4826T>C p.I1609T | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAHD2B | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 104/194 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAIM2 | c.15G>A p.K5= | Splice Region (SNP) | VAF 48/155 reads (31%) | called by muse, mutect2, varscan2
- FAM166A | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 37/41 reads (90%) | SIFT tolerated (0.11); PolyPhen benign (0.196); called by muse, varscan2
- FAM207A | c.353-1G>C p.X118_splice | Splice Site (SNP) | VAF 217/239 reads (91%) | called by muse, mutect2, varscan2
- FAM71F1 | c.736C>T p.Q246* | Nonsense Mutation (SNP) | VAF 98/229 reads (43%) | called by muse, mutect2, varscan2
- FAM83A | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 69/368 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FBXO7 | c.219G>C p.L73F | Missense Mutation (SNP) | VAF 139/157 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FDX1 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 65/73 reads (89%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGFR4 | c.1492A>T p.S498C | Missense Mutation (SNP) | VAF 173/196 reads (88%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- FILIP1 | c.3536G>T p.G1179V | Missense Mutation (SNP) | VAF 198/483 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- FLNC | c.5635A>T p.T1879S | Missense Mutation (SNP) | VAF 174/725 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FOLH1 | c.1480T>C p.Y494H | Missense Mutation (SNP) | VAF 55/64 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FRRS1 | c.1006+1G>A p.X336_splice | Splice Site (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- FSD1 | c.712G>C p.D238H | Missense Mutation (SNP) | VAF 65/138 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FSHR | c.1272T>A p.H424Q | Missense Mutation (SNP) | VAF 275/390 reads (71%) | SIFT tolerated (0.86); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FSIP2 | c.6715C>G p.Q2239E | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSIP2 | c.10330C>G p.L3444V | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- G6PC2 | c.218+1G>T p.X73_splice | Splice Site (SNP) | VAF 23/90 reads (26%) | called by muse, mutect2, varscan2
- GAB2 | c.186C>G p.N62K (on ENST00000361507 / NM_080491.3; = p.N24K on NM_012296.3) | Missense Mutation (SNP) | VAF 423/466 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- GABRG3 | c.539T>C p.M180T | Missense Mutation (SNP) | VAF 131/160 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GAGE2E | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 114/1828 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- GAL3ST2 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 157/244 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GCKR | c.1813C>G p.L605V | Missense Mutation (SNP) | VAF 20/618 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.104); called by muse, mutect2
- GEN1 | c.2164G>T p.D722Y | Missense Mutation (SNP) | VAF 88/101 reads (87%) | SIFT deleterious (0); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- GHR | c.1111G>C p.E371Q | Missense Mutation (SNP) | VAF 248/711 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GIPR | c.871G>C p.E291Q | Missense Mutation (SNP) | VAF 385/686 reads (56%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- GLB1L3 | c.220G>T p.G74C | Missense Mutation (SNP) | VAF 177/193 reads (92%) | SIFT deleterious (0.02); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- GNPNAT1 | c.152G>C p.R51T | Missense Mutation (SNP) | VAF 46/80 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); called by muse, varscan2
- GOLGA6L6 | c.1267C>A p.Q423K | Missense Mutation (SNP) | VAF 37/379 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- GPN2 | c.87G>C p.M29I | Missense Mutation (SNP) | VAF 122/215 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- GPR152 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 275/396 reads (69%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GPR162 | c.1540C>G p.L514V (on ENST00000311268 / NM_019858.2; = p.L230V on NM_014449.2) | Missense Mutation (SNP) | VAF 130/717 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GPRIN1 | c.1355C>T p.S452F | Missense Mutation (SNP) | VAF 145/168 reads (86%) | SIFT tolerated (0.09); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- GRM7 | c.1011G>T p.Q337H | Missense Mutation (SNP) | VAF 75/81 reads (93%) | SIFT deleterious (0.04); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- HCN2 | c.1090G>T p.V364L | Missense Mutation (SNP) | VAF 148/170 reads (87%) | SIFT deleterious (0.04); PolyPhen benign (0.241); called by mutect2, varscan2
- HDAC5 | c.3235G>A p.E1079K | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- HEPHL1 | c.1797G>C p.Q599H | Missense Mutation (SNP) | VAF 51/65 reads (78%) | SIFT tolerated (0.07); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- HLTF | c.2006C>A p.T669K | Missense Mutation (SNP) | VAF 68/187 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- HLX | c.1409C>A p.T470K | Missense Mutation (SNP) | VAF 76/136 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HMCN1 | c.3091G>T p.G1031* | Nonsense Mutation (SNP) | VAF 158/518 reads (31%) | called by muse, mutect2, varscan2
- HNRNPM | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 92/214 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HPS3 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 40/70 reads (57%) | called by muse, mutect2, varscan2
- HTT | c.8281G>C p.E2761Q | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ICOS | c.246C>A p.F82L | Missense Mutation (SNP) | VAF 94/175 reads (54%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IFT122 | c.1396G>T p.E466* (on ENST00000348417 / NM_052989.3; = p.E407* on NM_018262.4) | Nonsense Mutation (SNP) | VAF 355/852 reads (42%) | called by muse, mutect2, varscan2
- IGFBP1 | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 159/376 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- IGKV1-6 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 262/651 reads (40%) | called by muse, mutect2, varscan2
- IMMT | c.1237G>T p.D413Y | Missense Mutation (SNP) | VAF 253/631 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- IMPG2 | c.3373A>G p.R1125G | Missense Mutation (SNP) | VAF 176/430 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.11); called by muse, mutect2
- INPP5B | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGA8 | c.2644G>T p.A882S | Missense Mutation (SNP) | VAF 124/406 reads (31%) | SIFT tolerated (0.85); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ITPRID2 | c.2212C>T p.Q738* | Nonsense Mutation (SNP) | VAF 136/245 reads (56%) | called by muse, mutect2, varscan2
- KCNA1 | c.939G>T p.Q313H | Missense Mutation (SNP) | VAF 156/441 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KCNC2 | c.747A>T p.E249D | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KCNMB3 | c.25C>G p.Q9E | Missense Mutation (SNP) | VAF 152/423 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KCNMB4 | c.330C>G p.N110K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- KIF1A | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- KIFC2 | c.1109G>C p.G370A | Missense Mutation (SNP) | VAF 311/418 reads (74%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- KIR2DL4 | c.556A>T p.S186C (on ENST00000396284; = p.S147C on NM_001080770.2) | Missense Mutation (SNP) | VAF 138/217 reads (64%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLHL21 | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KRBA1 | c.1310G>C p.R437T | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- KRTAP10-4 | c.803A>G p.Q268R | Missense Mutation (SNP) | VAF 585/645 reads (91%) | SIFT tolerated (0.2); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- LBHD1 | c.358G>A p.E120K (on ENST00000431002 / NM_001367940.1; = p.E94K on NM_024099.3) | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- LCN8 | c.403C>G p.R135G (on ENST00000612714 / NM_001345934.1; = p.R112G on NM_178469.3) | Missense Mutation (SNP) | VAF 148/236 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LCNL1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 302/329 reads (92%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- LHX9 | c.377G>T p.R126I | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LOX | c.1214A>T p.H405L | Missense Mutation (SNP) | VAF 131/144 reads (91%) | SIFT tolerated (0.35); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- LOXHD1 | c.4470C>A p.D1490E | Missense Mutation (SNP) | VAF 115/136 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LPA | c.4378T>A p.C1460S | Missense Mutation (SNP) | VAF 174/451 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LRFN5 | c.92C>G p.P31R | Missense Mutation (SNP) | VAF 88/148 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- LRP2 | c.11587G>T p.G3863C | Missense Mutation (SNP) | VAF 327/510 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MALRD1 | c.2512A>T p.I838L | Missense Mutation (SNP) | VAF 400/592 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- MAP3K21 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MCF2 | c.2657C>A p.A886E | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT tolerated (0.05); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- MDN1 | c.15370G>T p.V5124L | Missense Mutation (SNP) | VAF 203/495 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MED14 | c.4208G>A p.R1403K | Missense Mutation (SNP) | VAF 222/254 reads (87%) | SIFT tolerated (0.44); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MED16 | c.492C>G p.F164L | Missense Mutation (SNP) | VAF 66/72 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MEPCE | c.2057C>A p.S686Y | Missense Mutation (SNP) | VAF 100/208 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.034); called by muse, varscan2
- MET | c.3791C>T p.S1264L | Missense Mutation (SNP) | VAF 108/274 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MFSD8 | c.1079A>T p.Q360L | Missense Mutation (SNP) | VAF 171/198 reads (86%) | SIFT tolerated (0.17); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- MIS18BP1 | c.1953A>C p.L651F | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MKI67 | c.6526G>T p.G2176C | Missense Mutation (SNP) | VAF 226/246 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MPP2 | c.947G>C p.R316P (on ENST00000461854 / NM_001278372.2; = p.R292P on NM_005374.5) | Missense Mutation (SNP) | VAF 110/422 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MS4A3 | c.518T>C p.M173T | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MSI2 | c.814G>T p.G272C | Missense Mutation (SNP) | VAF 232/259 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MTUS2 | c.1993G>A p.V665M | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- MYH10 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MYH13 | c.3320A>T p.Q1107L | Missense Mutation (SNP) | VAF 105/118 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MYLK | c.5446C>A p.R1816S | Missense Mutation (SNP) | VAF 245/473 reads (52%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- MYO15A | c.6631C>T p.L2211F | Missense Mutation (SNP) | VAF 87/319 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO7B | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 36/83 reads (43%) | called by muse, mutect2, varscan2
- MYPOP | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- NBR1 | c.2311G>C p.E771Q | Missense Mutation (SNP) | VAF 179/306 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- NCKAP5 | c.3796C>G p.L1266V | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- NCKAP5L | c.2775G>C p.K925N | Missense Mutation (SNP) | VAF 94/399 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NDC1 | c.71G>T p.R24M | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NDST2 | c.1566C>T p.I522= | Splice Region (SNP) | VAF 45/149 reads (30%) | called by muse, mutect2, varscan2
- NEU2 | c.455G>T p.R152L | Missense Mutation (SNP) | VAF 61/230 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- NFATC3 | c.2530C>T p.L844F | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NME9 | c.54G>C p.E18D | Missense Mutation (SNP) | VAF 22/275 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.949); called by muse, mutect2
- NOL4L | c.391G>C p.D131H | Missense Mutation (SNP) | VAF 89/427 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOS1 | c.1480G>C p.D494H | Missense Mutation (SNP) | VAF 115/407 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NSUN6 | c.923G>C p.G308A | Missense Mutation (SNP) | VAF 37/299 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NT5C2 | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 67/259 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- NTN4 | c.337C>A p.H113N | Missense Mutation (SNP) | VAF 82/316 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.348); called by muse, varscan2
- NUS1 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 54/400 reads (14%) | called by muse, varscan2
- NYAP1 | c.728del p.G243Afs*22 | Frame Shift Del (DEL) | VAF 51/123 reads (41%) | called by mutect2, pindel, varscan2
- OR10H5 | c.113C>A p.T38K | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- OR11H12 | c.223T>C p.Y75H | Missense Mutation (SNP) | VAF 253/693 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- OR1J4 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 207/230 reads (90%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- OR2A12 | c.334C>A p.L112M | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- OR2C3 | c.745G>A p.V249M | Missense Mutation (SNP) | VAF 115/429 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- OR2M2 | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); called by mutect2, varscan2
- OR4A5 | c.529G>T p.D177Y | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR4K15 | c.480G>C p.M160I (on ENST00000305051; = p.M136I on NM_001005486.1) | Missense Mutation (SNP) | VAF 60/232 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- OR56A1 | c.740A>T p.H247L | Missense Mutation (SNP) | VAF 102/110 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- OR5B12 | c.476G>T p.G159V | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- OR5K3 | c.67C>G p.L23V | Missense Mutation (SNP) | VAF 87/180 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- OR8G2P | c.329C>A p.A110E | Missense Mutation (SNP) | VAF 187/206 reads (91%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- OTOG | c.3145C>G p.L1049V | Missense Mutation (SNP) | VAF 96/113 reads (85%) | SIFT tolerated (0.23); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- OTOG | c.7441G>T p.E2481* | Nonsense Mutation (SNP) | VAF 221/247 reads (89%) | called by muse, mutect2, varscan2
- OTOG | c.8440G>C p.E2814Q | Missense Mutation (SNP) | VAF 166/176 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- PALD1 | c.1159G>T p.D387Y | Missense Mutation (SNP) | VAF 249/293 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- PAPPA2 | c.3122A>T p.H1041L | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PAXIP1 | c.1258C>T p.Q420* | Nonsense Mutation (SNP) | VAF 100/226 reads (44%) | called by muse, varscan2
- PCDHA9 | c.2096A>T p.Y699F | Missense Mutation (SNP) | VAF 302/354 reads (85%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PCDHAC1 | c.2560A>T p.T854S | Missense Mutation (SNP) | VAF 129/152 reads (85%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- PCDHAC2 | c.2329C>T p.H777Y | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PCNX1 | c.6154A>G p.T2052A | Missense Mutation (SNP) | VAF 179/313 reads (57%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDCD6IP | c.1589T>C p.L530P | Missense Mutation (SNP) | VAF 103/111 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDE3B | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 110/118 reads (93%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- PDPR | c.1056G>T p.M352I | Missense Mutation (SNP) | VAF 99/286 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHKB | c.2953G>C p.D985H | Missense Mutation (SNP) | VAF 68/224 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- PIK3CG | c.2369G>C p.G790A | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PIKFYVE | c.1730C>G p.S577C | Missense Mutation (SNP) | VAF 70/256 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- PLCG1 | c.2811C>T p.L937= | Splice Region (SNP) | VAF 58/208 reads (28%) | called by muse, mutect2, varscan2
- PLEKHB2 | c.803C>A p.A268D | Missense Mutation (SNP) | VAF 34/76 reads (45%) | PolyPhen benign (0.003); called by mutect2, varscan2
- PLEKHG7 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 103/414 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- PLG | c.2239G>T p.G747W | Missense Mutation (SNP) | VAF 106/477 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLPPR3 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 65/75 reads (87%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- PLPPR4 | c.1489C>A p.P497T | Missense Mutation (SNP) | VAF 144/309 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- PLSCR4 | c.174G>C p.M58I | Missense Mutation (SNP) | VAF 212/416 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- POGZ | c.2764A>T p.T922S | Missense Mutation (SNP) | VAF 270/353 reads (76%) | SIFT tolerated (0.87); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPEF2 | c.1317del p.R439Sfs*4 | Frame Shift Del (DEL) | VAF 46/68 reads (68%) | called by mutect2, pindel, varscan2
- PPP1R36 | c.341G>A p.G114D | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT tolerated (0.58); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PPP1R3E | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 87/137 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- PRAMEF10 | c.1424_*9del | Nonstop Mutation (DEL) | VAF 56/378 reads (15%) | called by mutect2, varscan2
- PRDM14 | c.1672C>A p.Q558K | Missense Mutation (SNP) | VAF 134/167 reads (80%) | SIFT tolerated (0.44); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PRKDC | c.2132G>T p.G711V | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- PRR23A | c.472G>T p.E158* | Nonsense Mutation (SNP) | VAF 281/602 reads (47%) | called by muse, mutect2, varscan2
- PSMB4 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 1035/1318 reads (79%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PSMB5 | c.559G>T p.V187L | Missense Mutation (SNP) | VAF 100/360 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- PTH2R | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 65/113 reads (58%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PTPRB | c.2606C>A p.T869N | Missense Mutation (SNP) | VAF 85/355 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PTPRU | c.1664C>A p.S555Y | Missense Mutation (SNP) | VAF 378/692 reads (55%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- PURB | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 80/208 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.048); called by mutect2, varscan2
- PYGO2 | c.543G>C p.Q181H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- QRICH1 | c.849G>T p.R283S | Missense Mutation (SNP) | VAF 64/89 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- QRICH1 | c.848G>T p.R283M | Missense Mutation (SNP) | VAF 63/87 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- RAD54L2 | c.1275G>C p.K425N | Missense Mutation (SNP) | VAF 63/83 reads (76%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- RALGAPA1 | c.5674G>T p.D1892Y | Missense Mutation (SNP) | VAF 73/146 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- RASA3 | c.2018C>T p.T673I | Missense Mutation (SNP) | VAF 117/157 reads (75%) | SIFT deleterious (0.03); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- RASD1 | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 162/471 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- RCBTB1 | c.239G>T p.S80I | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- RELB | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 181/315 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RGSL1 | c.518A>T p.E173V | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RHAG | c.761C>A p.A254D | Missense Mutation (SNP) | VAF 288/617 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- RILPL1 | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 77/296 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RIMS2 | c.1151C>G p.S384C (on ENST00000666250 / NM_001348490.2; = p.S192C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/235 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RLF | c.2854A>G p.T952A | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- RLN1 | c.411A>T p.Q137H | Missense Mutation (SNP) | VAF 113/134 reads (84%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- RNASET2 | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 155/395 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- RND3 | c.706G>C p.D236H | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, varscan2
- RNF19B | c.702G>C p.Q234H | Missense Mutation (SNP) | VAF 108/437 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- RPGR | c.2781T>G p.D927E (on ENST00000339363 / NM_001367249.1; = p.D722E on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RPS6KC1 | c.3175G>T p.V1059L | Missense Mutation (SNP) | VAF 51/222 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- RYR1 | c.2407C>A p.P803T | Missense Mutation (SNP) | VAF 222/873 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RYR1 | c.2596C>G p.L866V | Missense Mutation (SNP) | VAF 357/594 reads (60%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCFD2 | c.1936G>T p.V646L | Missense Mutation (SNP) | VAF 73/244 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- SCN2A | c.430G>T p.V144L | Missense Mutation (SNP) | VAF 84/156 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- SDCCAG8 | c.1152G>C p.E384D | Missense Mutation (SNP) | VAF 63/261 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SEMG2 | c.388C>G p.H130D | Missense Mutation (SNP) | VAF 54/102 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- SH3BP1 | c.15G>C p.Q5H | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SIPA1L1 | c.4132G>C p.E1378Q | Missense Mutation (SNP) | VAF 335/559 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- SLC1A6 | c.116T>A p.L39Q | Missense Mutation (SNP) | VAF 318/356 reads (89%) | SIFT tolerated (0.52); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- SLC2A3 | c.1249G>T p.G417* | Nonsense Mutation (SNP) | VAF 211/555 reads (38%) | called by muse, mutect2, varscan2
- SLC35F1 | c.958G>T p.D320Y | Missense Mutation (SNP) | VAF 127/301 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC47A1 | c.1312C>T p.L438= | Splice Region (SNP) | VAF 24/94 reads (26%) | called by muse, mutect2, varscan2
- SLC66A3 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 11/344 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); called by muse, mutect2
- SLC8A2 | c.1127C>G p.S376W | Missense Mutation (SNP) | VAF 178/293 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- SLC9C2 | c.2278A>G p.I760V | Missense Mutation (SNP) | VAF 44/71 reads (62%) | SIFT tolerated (0.23); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SMAP1 | c.496-1G>C p.X166_splice (on ENST00000370455 / NM_001044305.3; = p.X139_splice on NM_021940.5) | Splice Site (SNP) | VAF 37/84 reads (44%) | called by muse, mutect2, varscan2
- SMARCA4 | c.797C>A p.S266* | Nonsense Mutation (SNP) | VAF 107/284 reads (38%) | called by muse, mutect2, varscan2
- SMPD4 | c.1032del p.A345Pfs*29 | Frame Shift Del (DEL) | VAF 83/221 reads (38%) | called by mutect2, pindel, varscan2
- SNED1 | c.3487G>T p.D1163Y | Missense Mutation (SNP) | VAF 165/571 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPAG17 | c.3004G>T p.E1002* | Nonsense Mutation (SNP) | VAF 67/154 reads (44%) | called by muse, mutect2, varscan2
- SPHKAP | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 63/210 reads (30%) | called by muse, mutect2, varscan2
- SPTBN1 | c.1910C>T p.S637F | Missense Mutation (SNP) | VAF 178/344 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SRSF2 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 202/328 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- STAB1 | c.4199G>C p.C1400S | Missense Mutation (SNP) | VAF 27/31 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STAM | c.271A>T p.S91C | Missense Mutation (SNP) | VAF 166/284 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- STIM2 | c.455C>G p.P152R | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SUGP2 | c.1135G>T p.D379Y | Missense Mutation (SNP) | VAF 41/50 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SUZ12 | c.1595+1G>T p.X532_splice | Splice Site (SNP) | VAF 69/76 reads (91%) | called by mutect2, varscan2
- SYNE2 | c.17336C>A p.S5779Y | Missense Mutation (SNP) | VAF 134/208 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- SYNRG | c.220C>G p.Q74E | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SYNRG | c.78-3C>T | Splice Region (SNP) | VAF 23/86 reads (27%) | called by muse, mutect2, varscan2
- SYT16 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 85/306 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- SZT2 | c.8647G>T p.G2883W (on ENST00000634258 / NM_001365999.1; = p.G2826W on NM_015284.4) | Missense Mutation (SNP) | VAF 95/340 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- TAF4 | c.1585C>T p.Q529* | Nonsense Mutation (SNP) | VAF 160/374 reads (43%) | called by muse, mutect2, varscan2
- TAL1 | c.943C>A p.R315S | Missense Mutation (SNP) | VAF 85/259 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- TCEA1 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TERF2 | c.1054C>G p.Q352E | Missense Mutation (SNP) | VAF 175/288 reads (61%) | SIFT tolerated (0.94); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- TGFBR1 | c.1108A>T p.N370Y | Missense Mutation (SNP) | VAF 81/96 reads (84%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- THBS2 | c.820G>C p.G274R | Missense Mutation (SNP) | VAF 116/412 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- THUMPD3 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 222/242 reads (92%) | SIFT tolerated (0.33); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TIGD6 | c.441G>T p.M147I | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TIMELESS | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 151/255 reads (59%) | SIFT tolerated (0.75); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TIMM8A | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 147/163 reads (90%) | called by muse, mutect2, varscan2
- TM6SF1 | c.952C>T p.H318Y | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMEM163 | c.337A>T p.R113W | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMEM94 | c.2830G>A p.E944K | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TNIK | c.699_700del p.C234* | Frame Shift Del (DEL) | VAF 82/183 reads (45%) | called by pindel, varscan2
- TNRC6B | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TOPAZ1 | c.1630T>A p.S544T | Missense Mutation (SNP) | VAF 133/147 reads (90%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- TOR4A | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 243/265 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAV8-7 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 69/234 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- TRIM42 | c.1649A>T p.K550M | Missense Mutation (SNP) | VAF 139/362 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- TRPC3 | c.1940T>C p.V647A (on ENST00000379645 / NM_001366479.2; = p.V574A on NM_003305.2) | Missense Mutation (SNP) | VAF 138/159 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TRRAP | c.8916G>C p.K2972N (on ENST00000359863 / NM_001244580.1; = p.K2954N on NM_003496.3) | Missense Mutation (SNP) | VAF 131/308 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSHR | c.317+8C>A | Splice Region (SNP) | VAF 51/249 reads (20%) | called by muse, mutect2, varscan2
- TTC19 | c.382C>G p.Q128E | Missense Mutation (SNP) | VAF 196/359 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTLL7 | c.609C>G p.D203E | Missense Mutation (SNP) | VAF 57/98 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- TTN | c.76489G>C p.D25497H (on ENST00000591111; = p.D18073H on NM_003319.4) | Missense Mutation (SNP) | VAF 44/138 reads (32%) | PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- TTN | c.19903G>C p.E6635Q (on ENST00000591111; = p.E5708Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/41 reads (63%) | PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- TTN | c.8568C>G p.I2856M (on ENST00000591111; = p.I2810M on NM_003319.4) | Missense Mutation (SNP) | VAF 80/308 reads (26%) | PolyPhen possibly damaging (0.682); called by muse, varscan2
- TUT7 | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 42/52 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TXK | c.486T>A p.H162Q | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TXNRD2 | c.547C>G p.H183D | Missense Mutation (SNP) | VAF 343/777 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- U2AF2 | c.1403C>T p.S468F | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- UCHL5 | c.359G>T p.S120I | Missense Mutation (SNP) | VAF 63/102 reads (62%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- UHRF1BP1L | c.583A>T p.T195S | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- UROC1 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 235/569 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- USP21 | c.1115-1G>C p.X372_splice | Splice Site (SNP) | VAF 65/232 reads (28%) | called by muse, mutect2, varscan2
- USP42 | c.1927G>C p.D643H | Missense Mutation (SNP) | VAF 115/217 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- USP9X | c.3968G>T p.C1323F | Missense Mutation (SNP) | VAF 44/45 reads (98%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- UTP14C | c.1433C>T p.S478L | Missense Mutation (SNP) | VAF 90/128 reads (70%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- UTP18 | c.587G>T p.W196L | Missense Mutation (SNP) | VAF 129/155 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VIRMA | c.170G>T p.R57I | Missense Mutation (SNP) | VAF 204/275 reads (74%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- VKORC1L1 | c.214C>G p.L72V | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- VWA8 | c.2530C>G p.L844V | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- WASF3 | c.1051G>T p.V351L | Missense Mutation (SNP) | VAF 183/419 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR20 | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 203/712 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDR64 | c.2237G>A p.S746N | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- WIZ | c.4907G>C p.C1636S (on ENST00000673675 / NM_001371589.1; = p.C541S on NM_021241.3) | Missense Mutation (SNP) | VAF 74/88 reads (84%) | SIFT tolerated (0.61); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- WNT7A | c.1000G>T p.V334F | Missense Mutation (SNP) | VAF 87/98 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- YLPM1 | c.4444G>C p.E1482Q | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ZFP28 | c.1204C>T p.Q402* | Nonsense Mutation (SNP) | VAF 21/58 reads (36%) | called by muse, mutect2, varscan2
- ZFP69B | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 142/303 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ZNF217 | c.1609G>T p.G537C | Missense Mutation (SNP) | VAF 149/315 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF300 | c.143-1G>C p.X48_splice | Splice Site (SNP) | VAF 57/70 reads (81%) | called by muse, mutect2, varscan2
- ZNF318 | c.4744G>T p.E1582* | Nonsense Mutation (SNP) | VAF 129/280 reads (46%) | called by muse, varscan2
- ZNF318 | c.4570G>T p.E1524* | Nonsense Mutation (SNP) | VAF 121/268 reads (45%) | called by muse, mutect2, varscan2
- ZNF318 | c.4515G>A p.M1505I | Missense Mutation (SNP) | VAF 121/269 reads (45%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF335 | c.12C>A p.N4K | Missense Mutation (SNP) | VAF 292/494 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- ZNF410 | c.374_376delinsCT p.N125Tfs*2 | Frame Shift Del (DEL) | VAF 37/204 reads (18%) | called by pindel, varscan2*
- ZNF552 | c.33+8T>C | Splice Region (SNP) | VAF 80/297 reads (27%) | called by muse, mutect2, varscan2
- ZNF638 | c.689A>G p.D230G | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF674 | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 37/41 reads (90%) | SIFT tolerated (0.32); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- ZNF786 | c.1834C>T p.Q612* | Nonsense Mutation (SNP) | VAF 96/425 reads (23%) | called by muse, mutect2, varscan2
- ZNF804A | c.1553A>T p.N518I | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- ZNF831 | c.2758G>T p.A920S | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- ZNF98 | c.1573A>G p.K525E | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- ZXDA | c.1423G>T p.D475Y | Missense Mutation (SNP) | VAF 100/245 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ZZEF1 | c.8248G>T p.D2750Y | Missense Mutation (SNP) | VAF 166/307 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZZEF1 | c.4559C>A p.S1520Y | Missense Mutation (SNP) | VAF 286/482 reads (59%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ABCC8 | c.403C>T p.L135= | Silent (SNP) | VAF 160/605 reads (26%) | catalogued as CM107074; called by muse, mutect2, varscan2
- ACP3 | c.837C>T p.S279= | Silent (SNP) | VAF 34/114 reads (30%) | called by muse, mutect2, varscan2
- ACSF2 | c.1629G>A p.V543= | Silent (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2
- ADAM7 | c.1038C>T p.D346= | Silent (SNP) | VAF 67/84 reads (80%) | catalogued as rs745392106, COSV51544698; called by muse, mutect2, varscan2
- AGRN | c.4260C>T p.F1420= | Silent (SNP) | VAF 189/315 reads (60%) | catalogued as rs985182576; called by muse, mutect2, varscan2
- AL121899.2 | c.1629C>T p.I543= | Silent (SNP) | VAF 41/135 reads (30%) | called by muse, mutect2, varscan2
- AMY2A | c.534T>A p.T178= | Silent (SNP) | VAF 62/530 reads (12%) | called by muse, mutect2, varscan2
- ANKRD13B | c.486G>C p.L162= | Silent (SNP) | VAF 94/375 reads (25%) | called by muse, mutect2, varscan2
- AP002512.3 | c.1212C>G p.V404= | Silent (SNP) | VAF 18/71 reads (25%) | called by muse, mutect2, varscan2
- ARHGEF33 | c.237C>T p.F79= | Silent (SNP) | VAF 38/42 reads (90%) | called by muse, mutect2, varscan2
- ARMC9 | c.2109G>A p.P703= | Silent (SNP) | VAF 25/232 reads (11%) | catalogued as rs781559742; called by muse, mutect2
- BLK | c.1239C>T p.T413= | Silent (SNP) | VAF 92/125 reads (74%) | called by muse, mutect2, varscan2
- BPIFA2 | c.660C>T p.I220= | Silent (SNP) | VAF 142/590 reads (24%) | catalogued as COSV99487895; called by muse, mutect2, varscan2
- BRINP1 | c.1296G>A p.G432= | Silent (SNP) | VAF 114/125 reads (91%) | catalogued as COSV56304204, COSV99774065; called by muse, mutect2, varscan2
- BTF3 | c.165C>T p.L55= (on ENST00000380591 / NM_001037637.1; = p.L11= on NM_001207.4) | Silent (SNP) | VAF 81/92 reads (88%) | catalogued as rs1478096824, COSV60063751; called by muse, mutect2, varscan2
- C1orf141 | c.528C>T p.C176= | Silent (SNP) | VAF 35/67 reads (52%) | called by muse, mutect2, varscan2
- CADPS | c.2193C>A p.L731= | Silent (SNP) | VAF 101/120 reads (84%) | called by muse, mutect2, varscan2
- CALB2 | c.537C>A p.L179= | Silent (SNP) | VAF 129/226 reads (57%) | catalogued as COSV56939738; called by muse, mutect2, varscan2
- CASP9 | c.843C>G p.L281= | Silent (SNP) | VAF 56/161 reads (35%) | catalogued as COSV61601493; called by muse, mutect2, varscan2
- CCN1 | c.15C>T p.I5= | Silent (SNP) | VAF 29/136 reads (21%) | catalogued as rs1193156033, COSV71704336; called by muse, mutect2, varscan2
- CD300A | c.675G>T p.T225= | Silent (SNP) | VAF 181/201 reads (90%) | called by muse, mutect2, varscan2
- CDH11 | c.1512A>C p.P504= | Silent (SNP) | VAF 40/138 reads (29%) | catalogued as COSV51752496; called by muse, mutect2, varscan2
- CDH26 | c.1905G>C p.L635= | Silent (SNP) | VAF 121/278 reads (44%) | called by muse, mutect2, varscan2
- CDH9 | c.1770C>T p.A590= | Silent (SNP) | VAF 99/372 reads (27%) | catalogued as COSV99149714; called by muse, mutect2, varscan2
- CELSR2 | c.195C>T p.L65= | Silent (SNP) | VAF 80/178 reads (45%) | catalogued as rs1392193176; called by muse, mutect2, varscan2
- CFHR1 | c.642T>C p.I214= | Silent (SNP) | VAF 104/138 reads (75%) | called by muse, mutect2, varscan2
- CFHR2 | c.258G>T p.L86= | Silent (SNP) | VAF 69/139 reads (50%) | called by muse, mutect2, varscan2
- CNEP1R1 | c.303G>A p.T101= (on ENST00000427478 / NM_001281789.1; = p.T118= on NM_153261.5) | Silent (SNP) | VAF 37/156 reads (24%) | catalogued as rs772216625; called by muse, mutect2, varscan2
- CNTNAP4 | c.1734T>C p.T578= | Silent (SNP) | VAF 109/203 reads (54%) | catalogued as rs762716596, COSV56704868; called by muse, mutect2, varscan2
- COL20A1 | c.3309C>T p.V1103= | Silent (SNP) | VAF 86/242 reads (36%) | catalogued as rs1321919919; called by muse, mutect2, varscan2
- COL5A1 | c.1560C>T p.L520= | Silent (SNP) | VAF 472/528 reads (89%) | called by muse, varscan2
- CRMP1 | c.1398C>G p.G466= | Silent (SNP) | VAF 162/359 reads (45%) | called by muse, mutect2, varscan2
- CSF3R | c.2340C>T p.L780= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV58970062; called by muse, mutect2, varscan2
- CTRL | c.9G>A p.L3= | Silent (SNP) | VAF 208/339 reads (61%) | catalogued as rs1376492469; called by muse, mutect2, varscan2
- DDR1 | c.2448C>T p.L816= (on ENST00000324771; = p.L779= on NM_001954.4) | Silent (SNP) | VAF 53/108 reads (49%) | catalogued as rs779373025; called by muse, mutect2, varscan2
- DNAH11 | c.12279G>C p.G4093= | Silent (SNP) | VAF 126/351 reads (36%) | called by muse, mutect2, varscan2
- DUS3L | c.1575C>G p.L525= | Silent (SNP) | VAF 84/96 reads (88%) | catalogued as rs1023669688; called by muse, mutect2, varscan2
- DYNAP | c.255C>T p.I85= (on ENST00000321600; = p.I59= on NM_173629.3) | Silent (SNP) | VAF 91/103 reads (88%) | catalogued as COSV58665998; called by muse, mutect2, varscan2
- EEF2KMT | c.426C>A p.A142= | Silent (SNP) | VAF 153/529 reads (29%) | called by muse, mutect2, varscan2
- EIF4A3 | c.54C>G p.L18= | Silent (SNP) | VAF 186/295 reads (63%) | called by muse, mutect2, varscan2
- ELMO1 | c.423G>A p.Q141= | Silent (SNP) | VAF 13/51 reads (25%) | called by muse, mutect2, varscan2
- EPHA4 | c.498G>T p.L166= | Silent (SNP) | VAF 53/165 reads (32%) | called by muse, mutect2, varscan2
- EPHA5 | c.2247G>C p.V749= | Silent (SNP) | VAF 25/29 reads (86%) | called by muse, mutect2, varscan2
- EPHB4 | c.2844C>G p.L948= | Silent (SNP) | VAF 75/182 reads (41%) | called by muse, mutect2, varscan2
- ERH | c.201C>G p.L67= | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as COSV53680574; called by muse, mutect2, varscan2
- ERICH3 | c.4575C>A p.P1525= | Silent (SNP) | VAF 55/89 reads (62%) | called by muse, mutect2, varscan2
- ETV3L | c.90C>T p.A30= | Silent (SNP) | VAF 110/360 reads (31%) | catalogued as rs750838692, COSV71901203; called by muse, mutect2, varscan2
- EVC2 | c.378C>G p.S126= | Silent (SNP) | VAF 119/275 reads (43%) | called by muse, mutect2, varscan2
- EYS | c.3390C>T p.I1130= | Silent (SNP) | VAF 128/347 reads (37%) | called by muse, mutect2, varscan2
- FAM102A | c.66T>A p.T22= | Silent (SNP) | VAF 132/215 reads (61%) | called by muse, mutect2, varscan2
- FOXG1 | c.384C>T p.G128= | Silent (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2, varscan2
- GIMAP1 | c.831C>A p.G277= | Silent (SNP) | VAF 141/346 reads (41%) | called by muse, mutect2, varscan2
- GPR88 | c.927C>T p.F309= | Silent (SNP) | VAF 235/560 reads (42%) | catalogued as rs541880945, COSV59291096; called by muse, mutect2, varscan2
- GPRIN3 | c.24G>C p.L8= | Silent (SNP) | VAF 59/66 reads (89%) | called by muse, mutect2, varscan2
- HHATL | c.501C>A p.G167= | Silent (SNP) | VAF 182/199 reads (91%) | catalogued as COSV60042918; called by muse, mutect2, varscan2
- HLA-DOA | c.660C>A p.V220= | Silent (SNP) | VAF 198/427 reads (46%) | called by muse, mutect2, varscan2
- HOOK1 | c.2091G>A p.A697= | Silent (SNP) | VAF 54/178 reads (30%) | catalogued as rs149212619; called by muse, mutect2, varscan2
- HSPG2 | c.12075C>T p.G4025= | Silent (SNP) | VAF 285/503 reads (57%) | catalogued as rs1240505848; called by muse, mutect2, varscan2
- IGHE | c.789G>A p.V263= | Silent (SNP) | VAF 158/504 reads (31%) | catalogued as rs782797265; called by muse, mutect2, varscan2
- IP6K1 | c.330G>A p.R110= | Silent (SNP) | VAF 169/219 reads (77%) | called by muse, mutect2, varscan2
- KCTD10 | c.678C>G p.V226= | Silent (SNP) | VAF 94/360 reads (26%) | called by muse, mutect2, varscan2
- KIF2A | c.699C>G p.L233= | Silent (SNP) | VAF 10/16 reads (63%) | called by muse, mutect2, varscan2
- KIF2B | c.642C>T p.I214= | Silent (SNP) | VAF 76/270 reads (28%) | called by muse, mutect2, varscan2
- KLF7 | c.330C>T p.L110= | Silent (SNP) | VAF 70/258 reads (27%) | catalogued as rs1480815061; called by muse, mutect2, varscan2
- KLHL33 | c.219C>A p.A73= | Silent (SNP) | VAF 195/300 reads (65%) | called by muse, mutect2, varscan2
- KLHL4 | c.876T>C p.D292= | Silent (SNP) | VAF 76/82 reads (93%) | called by muse, mutect2, varscan2
- KLKB1 | c.1521A>G p.K507= | Silent (SNP) | VAF 109/225 reads (48%) | called by muse, mutect2, varscan2
- KPNB1 | c.2361G>A p.V787= | Silent (SNP) | VAF 43/169 reads (25%) | catalogued as rs760610497; called by muse, mutect2, varscan2
- KRT7 | c.174G>C p.P58= | Silent (SNP) | VAF 204/340 reads (60%) | catalogued as rs544423621; called by muse, mutect2, varscan2
- LAMA2 | c.4803G>T p.P1601= | Silent (SNP) | VAF 278/592 reads (47%) | catalogued as rs766521929, COSV101370745; called by muse, mutect2, varscan2
- LOXHD1 | c.1254G>A p.R418= | Silent (SNP) | VAF 154/172 reads (90%) | called by muse, mutect2, varscan2
- LRCH4 | c.1953G>T p.P651= | Silent (SNP) | VAF 54/143 reads (38%) | called by muse, mutect2, varscan2
- LRP5 | c.4794G>A p.R1598= | Silent (SNP) | VAF 16/74 reads (22%) | called by mutect2, varscan2
- LRRC7 | c.3435G>T p.G1145= (on ENST00000651989 / NM_001370785.2; = p.G1112= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 62/187 reads (33%) | catalogued as rs773666243; called by muse, mutect2, varscan2
- LTB4R2 | c.438C>G p.L146= (on ENST00000528054; = p.L115= on NM_019839.5) | Silent (SNP) | VAF 337/555 reads (61%) | called by muse, mutect2, varscan2
- MDM1 | c.489A>G p.V163= | Silent (SNP) | VAF 25/74 reads (34%) | called by muse, mutect2, varscan2
- METTL11B | c.540C>T p.P180= | Silent (SNP) | VAF 57/209 reads (27%) | catalogued as COSV63029846; called by muse, mutect2, varscan2
- MKI67 | c.4782C>T p.L1594= | Silent (SNP) | VAF 318/351 reads (91%) | called by muse, mutect2, varscan2
- MMS19 | c.3078G>A p.G1026= | Silent (SNP) | VAF 92/108 reads (85%) | called by muse, mutect2, varscan2
- MSH2 | c.1221C>G p.L407= | Silent (SNP) | VAF 132/192 reads (69%) | catalogued as rs63750813, CD087394; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYH14 | c.2334C>T p.Y778= | Silent (SNP) | VAF 96/176 reads (55%) | called by muse, mutect2, varscan2
- MYH2 | c.2628G>A p.R876= | Silent (SNP) | VAF 112/394 reads (28%) | catalogued as COSV55431841; called by mutect2, varscan2
- NRG1 | c.363C>T p.D121= | Silent (SNP) | VAF 72/127 reads (57%) | catalogued as rs1317459926; called by muse, mutect2, varscan2
- NRXN3 | c.2685C>A p.L895= (on ENST00000335750 / NM_001330195.2; = p.L522= on NM_004796.6) | Silent (SNP) | VAF 132/220 reads (60%) | called by muse, mutect2, varscan2
- OAS2 | c.1572C>T p.F524= | Silent (SNP) | VAF 54/96 reads (56%) | catalogued as COSV60802459; called by muse, mutect2, varscan2
- OR56A1 | c.378T>C p.Y126= | Silent (SNP) | VAF 240/260 reads (92%) | called by muse, mutect2, varscan2
- OR5M11 | c.675C>G p.L225= | Silent (SNP) | VAF 34/87 reads (39%) | called by muse, mutect2, varscan2
- OR6K2 | c.291C>A p.L97= | Silent (SNP) | VAF 189/325 reads (58%) | catalogued as COSV62743473; called by muse, mutect2, varscan2
- OR8D2 | c.462G>T p.L154= | Silent (SNP) | VAF 212/224 reads (95%) | called by muse, mutect2, varscan2
- PBOV1 | c.24G>A p.Q8= | Silent (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
- PBXIP1 | c.1131A>G p.E377= | Silent (SNP) | VAF 191/327 reads (58%) | called by muse, mutect2, varscan2
- PCARE | c.3756T>A p.S1252= | Silent (SNP) | VAF 420/467 reads (90%) | called by muse, mutect2, varscan2
- PCDHA12 | c.2077C>T p.L693= | Silent (SNP) | VAF 162/380 reads (43%) | catalogued as COSV56496485; called by muse, varscan2
- PCDHA9 | c.1815G>C p.A605= | Silent (SNP) | VAF 368/429 reads (86%) | catalogued as COSV65326327; called by muse, mutect2, varscan2
- PCDHB10 | c.1983C>A p.L661= | Silent (SNP) | VAF 418/450 reads (93%) | called by muse, mutect2, varscan2
- PCNX1 | c.4113G>A p.L1371= | Silent (SNP) | VAF 23/43 reads (53%) | called by muse, mutect2, varscan2
- PFKM | c.63C>A p.V21= | Silent (SNP) | VAF 20/136 reads (15%) | called by muse, mutect2, varscan2
- PLXDC1 | c.534G>A p.L178= | Silent (SNP) | VAF 255/420 reads (61%) | catalogued as COSV59549454; called by muse, mutect2, varscan2
- PRAMEF15 | c.445T>C p.L149= | Silent (SNP) | VAF 190/1085 reads (18%) | catalogued as rs966946326; called by mutect2, varscan2
- PRRC2A | c.2580G>T p.G860= | Silent (SNP) | VAF 43/110 reads (39%) | called by muse, varscan2
- PTPRB | c.1239C>T p.F413= | Silent (SNP) | VAF 32/162 reads (20%) | catalogued as rs530187375, COSV54241008; called by muse, mutect2, varscan2
- RFX4 | c.510C>G p.P170= (on ENST00000392842 / NM_213594.3; = p.P76= on NM_032491.6) | Silent (SNP) | VAF 150/514 reads (29%) | catalogued as COSV99986084; called by muse, varscan2
- RFX4 | c.534G>A p.L178= (on ENST00000392842 / NM_213594.3; = p.L84= on NM_032491.6) | Silent (SNP) | VAF 242/404 reads (60%) | called by muse, varscan2
- RFX7 | c.2853G>T p.P951= (on ENST00000559447 / NM_001368074.1; = p.P1048= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 94/103 reads (91%) | called by muse, mutect2, varscan2
- RGS7 | c.1026T>C p.V342= | Silent (SNP) | VAF 120/243 reads (49%) | called by muse, mutect2
- RNASEH2A | c.189G>C p.L63= | Silent (SNP) | VAF 229/248 reads (92%) | called by muse, mutect2, varscan2
- RPA3 | c.228G>A p.K76= | Silent (SNP) | VAF 36/78 reads (46%) | called by muse, mutect2, varscan2
- RPH3A | c.1782G>A p.L594= (on ENST00000389385 / NM_001143854.2; = p.L590= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 88/356 reads (25%) | called by muse, varscan2
- RTF1 | c.786C>G p.S262= | Silent (SNP) | VAF 36/73 reads (49%) | called by muse, mutect2, varscan2
- RTN4 | c.3102C>T p.F1034= (on ENST00000337526 / NM_020532.5; = p.F41= on NM_007008.3) | Silent (SNP) | VAF 236/401 reads (59%) | called by muse, mutect2, varscan2
- RTN4IP1 | c.966C>T p.V322= | Silent (SNP) | VAF 86/171 reads (50%) | called by muse, mutect2, varscan2
- RXFP1 | c.210G>T p.L70= | Silent (SNP) | VAF 27/31 reads (87%) | called by muse, mutect2, varscan2
- SAMD4B | c.924C>G p.L308= | Silent (SNP) | VAF 197/268 reads (74%) | catalogued as rs761589111; called by muse, mutect2, varscan2
- SCYL1 | c.273C>T p.V91= | Silent (SNP) | VAF 49/175 reads (28%) | catalogued as rs374236882; called by muse, mutect2, varscan2
- SDS | c.405C>A p.P135= | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as COSV57454434; called by muse, mutect2, varscan2
- SEMA5B | c.291G>T p.L97= | Silent (SNP) | VAF 150/282 reads (53%) | called by muse, mutect2, varscan2
- SHISA4 | c.267C>T p.I89= | Silent (SNP) | VAF 57/218 reads (26%) | catalogued as rs763815716, COSV62884697; called by muse, mutect2, varscan2
- SLC12A5 | c.1626G>T p.V542= (on ENST00000454036 / NM_001134771.2; = p.V519= on NM_020708.5) | Silent (SNP) | VAF 22/66 reads (33%) | called by muse, mutect2, varscan2
- SLC17A5 | c.462C>A p.P154= | Silent (SNP) | VAF 121/254 reads (48%) | called by muse, mutect2, varscan2
- SLC34A1 | c.1131C>G p.L377= | Silent (SNP) | VAF 215/252 reads (85%) | called by muse, mutect2, varscan2
- SLC38A7 | c.987C>A p.I329= | Silent (SNP) | VAF 78/262 reads (30%) | catalogued as rs765625931; called by muse, mutect2, varscan2
- SLC39A12 | c.1479C>T p.N493= | Silent (SNP) | VAF 32/841 reads (4%) | called by muse, mutect2
- SLC39A9 | c.156A>G p.A52= | Silent (SNP) | VAF 121/467 reads (26%) | called by muse, mutect2, varscan2
- SLC44A5 | c.492G>T p.L164= | Silent (SNP) | VAF 28/112 reads (25%) | called by muse, mutect2, varscan2
- SLC6A18 | c.381C>T p.L127= | Silent (SNP) | VAF 48/409 reads (12%) | catalogued as COSV57249412; called by muse, mutect2, varscan2
- SLC6A18 | c.771A>T p.A257= | Silent (SNP) | VAF 140/399 reads (35%) | called by muse, mutect2, varscan2
- SLC9A4 | c.1845C>G p.L615= | Silent (SNP) | VAF 92/266 reads (35%) | called by muse, mutect2, varscan2
- SP4 | c.1797A>G p.T599= | Silent (SNP) | VAF 158/329 reads (48%) | called by muse, mutect2, varscan2
- SPEG | c.3352C>T p.L1118= | Silent (SNP) | VAF 44/165 reads (27%) | called by muse, mutect2, varscan2
- SPHKAP | c.2544C>T p.H848= | Silent (SNP) | VAF 45/179 reads (25%) | catalogued as rs1261453267; called by muse, mutect2, varscan2
- SPINT2 | c.123G>T p.S41= | Silent (SNP) | VAF 79/389 reads (20%) | catalogued as COSV100007450; called by muse, mutect2, varscan2
- SRR | c.744C>G p.T248= | Silent (SNP) | VAF 219/380 reads (58%) | called by muse, mutect2, varscan2
- SVOPL | c.123C>T p.I41= | Silent (SNP) | VAF 97/407 reads (24%) | catalogued as rs374224696; called by muse, mutect2, varscan2
- SYNE1 | c.10677G>A p.V3559= (on ENST00000367255 / NM_182961.4; = p.V3566= on NM_033071.3) | Silent (SNP) | VAF 53/248 reads (21%) | catalogued as COSV54969960; called by muse, mutect2, varscan2
- TAAR5 | c.549G>T p.L183= | Silent (SNP) | VAF 51/106 reads (48%) | called by muse, mutect2, varscan2
- TAS2R31 | c.96C>T p.S32= | Silent (SNP) | VAF 58/422 reads (14%) | catalogued as rs1359823648; called by muse, varscan2
- TCTEX1D4 | c.414G>C p.A138= | Silent (SNP) | VAF 51/287 reads (18%) | called by muse, mutect2, varscan2
- TEX55 | c.687G>C p.G229= | Silent (SNP) | VAF 129/248 reads (52%) | called by muse, mutect2, varscan2
- TIE1 | c.1821G>A p.L607= | Silent (SNP) | VAF 109/416 reads (26%) | called by muse, mutect2, varscan2
- TLK1 | c.1815C>T p.I605= | Silent (SNP) | VAF 21/43 reads (49%) | called by muse, mutect2, varscan2
- TLR4 | c.2166C>T p.I722= (on ENST00000355622 / NM_138554.5; = p.I682= on NM_003266.4) | Silent (SNP) | VAF 20/21 reads (95%) | catalogued as COSV62922632; called by muse, mutect2, varscan2
- TM4SF20 | c.552T>C p.H184= | Silent (SNP) | VAF 84/311 reads (27%) | catalogued as rs755572844; called by muse, mutect2, varscan2
- TPRX1 | c.279T>C p.S93= | Silent (SNP) | VAF 117/209 reads (56%) | called by muse, mutect2, varscan2
- TRAM2 | c.843C>T p.P281= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as rs900068359, COSV51733236; called by muse, mutect2, varscan2
- TTC22 | c.1101C>G p.A367= | Silent (SNP) | VAF 138/218 reads (63%) | called by muse, mutect2, varscan2
- TTN | c.75402G>A p.V25134= (on ENST00000591111; = p.V17710= on NM_003319.4) | Silent (SNP) | VAF 76/248 reads (31%) | catalogued as COSV60015436; called by muse, mutect2, varscan2
- TTN | c.21162C>A p.T7054= (on ENST00000591111; = p.T6127= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/230 reads (23%) | catalogued as COSV100635549; called by muse, mutect2, varscan2
- UBE4B | c.2748T>C p.V916= (on ENST00000343090 / NM_001105562.3; = p.V787= on NM_006048.5) | Silent (SNP) | VAF 90/282 reads (32%) | called by muse, mutect2, varscan2
- UBR7 | c.840A>C p.A280= | Silent (SNP) | VAF 89/324 reads (27%) | catalogued as rs889533878; called by muse, mutect2, varscan2
- USF3 | c.285A>G p.Q95= | Silent (SNP) | VAF 9/27 reads (33%) | called by mutect2, varscan2
- VAPB | c.105G>A p.P35= | Silent (SNP) | VAF 272/626 reads (43%) | catalogued as rs141383583; ClinVar: benign; called by muse, mutect2, varscan2
- VPS35L | c.123A>T p.T41= | Silent (SNP) | VAF 25/31 reads (81%) | catalogued as COSV104378621; called by muse, mutect2, varscan2
- WDR13 | c.693C>T p.I231= | Silent (SNP) | VAF 196/207 reads (95%) | catalogued as COSV54332667; called by muse, mutect2, varscan2
- XIRP2 | c.351C>T p.S117= (on ENST00000628543; = p.S292= on NM_152381.6) | Silent (SNP) | VAF 60/227 reads (26%) | called by muse, mutect2, varscan2
- YTHDF2 | c.645C>T p.S215= | Silent (SNP) | VAF 74/276 reads (27%) | called by muse, mutect2, varscan2
- ZFP57 | c.1047G>A p.K349= | Silent (SNP) | VAF 395/841 reads (47%) | catalogued as COSV100971794; called by muse, mutect2, varscan2
- ZFYVE26 | c.5460C>G p.V1820= | Silent (SNP) | VAF 270/460 reads (59%) | called by muse, mutect2, varscan2
- ZNF182 | c.1302G>A p.V434= | Silent (SNP) | VAF 58/65 reads (89%) | called by muse, mutect2, varscan2
- ZNF233 | c.1083G>A p.E361= | Silent (SNP) | VAF 80/138 reads (58%) | catalogued as COSV61934358; called by muse, mutect2, varscan2
- ZNF285 | c.753C>T p.H251= | Silent (SNP) | VAF 52/147 reads (35%) | called by muse, mutect2, varscan2
- ZNF341 | c.2397G>A p.A799= (on ENST00000375200 / NM_001282935.1; = p.A792= on NM_032819.4) | Silent (SNP) | VAF 59/245 reads (24%) | catalogued as rs548375525, COSV61005732; called by muse, mutect2, varscan2
- ZNF536 | c.765G>C p.V255= | Silent (SNP) | VAF 49/178 reads (28%) | called by muse, mutect2, varscan2
- ZNF560 | c.1920C>T p.S640= | Silent (SNP) | VAF 51/164 reads (31%) | catalogued as rs1295630876; called by muse, mutect2, varscan2
- ZNF568 | c.963C>A p.I321= | Silent (SNP) | VAF 44/64 reads (69%) | catalogued as rs1047260011; called by muse, mutect2, varscan2
119 further variants in this file (0 protein-altering or splice-affecting, 2 silent, 117 other) are not listed here.
